Somatic mutation profile of tumor specimen TCGA-HB-A5W3-01A (aliquot TCGA-HB-A5W3-01A-11D-A29N-09) from TCGA case TCGA-HB-A5W3, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 58.6 years (21,416 days).
Specimen TCGA-HB-A5W3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd9e1b2b-62df-4993-8be5-8aef3c35b9b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HB-A5W3-10A (Blood Derived Normal), aliquot TCGA-HB-A5W3-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb0a87ad-72f2-4fd0-a970-de31f2cac104

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 10, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 16/21 reads (76%) | hotspot (GDC flag); catalogued as COSV52734595, COSV53139118; called by muse, mutect2, varscan2
- ABCC3 | c.3807+1G>A p.X1269_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99560025; called by muse, mutect2, varscan2
- ARHGAP27 | c.1936G>A p.A646T (on ENST00000428638 / NM_001282290.1; = p.A305T on NM_199282.3) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.041); catalogued as rs1030053633; called by muse, mutect2, varscan2
- EDA | c.406T>A p.L136M | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100999636; called by muse, mutect2
- FRMD1 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1484993044; called by muse, mutect2, varscan2
- MCF2 | c.2176C>A p.L726I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as COSV100644436; called by muse, mutect2, varscan2
- MTNR1A | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs763569138, COSV56158274; called by muse, mutect2, varscan2
- PLPPR5 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54177494; called by muse, mutect2, varscan2
- PTPRM | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs754414099, COSV59869763; called by muse, mutect2, varscan2
- TAAR9 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV101453419; called by muse, mutect2
- ARHGEF17 | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CDH9 | c.1402C>G p.Q468E | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, varscan2
- DLK2 | c.168C>G p.H56Q | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DMD | c.3418C>A p.H1140N | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM5C | c.1472A>G p.N491S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- KLHL11 | c.955G>C p.V319L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC4 | c.2374T>C p.S792P | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- TFDP1 | c.101T>G p.V34G | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZHX1 | c.2002dup p.T668Nfs*3 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- ARL13A | c.114G>T p.V38= | Silent (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- HRNR | c.2493T>C p.H831= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs757559221; called by muse, mutect2, varscan2
- INPP4A | c.1329C>T p.G443= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- LRRC20 | c.363G>T p.A121= (on ENST00000355790 / NM_207119.3; = p.A71= on NM_018239.4) | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs758493647; called by muse, mutect2, varscan2
- PHYHIP | c.753C>T p.R251= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs112627300; called by muse, mutect2, varscan2
- RUSC2 | c.3846C>T p.I1282= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs952402016, COSV63428522; called by muse, mutect2, varscan2
- SAG | c.1206C>T p.D402= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs763213806; called by muse, mutect2, varscan2
- SLC27A2 | c.1137T>C p.G379= | Silent (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- TYK2 | c.3283C>T p.L1095= | Silent (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- ZBBX | c.1410T>C p.N470= | Silent (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- HTR4 | c.1077-1013G>C | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100090116; called by muse, mutect2
